Somatic mutation profile of tumor specimen C3L-08152-01 (aliquot CPT0511420006) from CPTAC case C3L-08152, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G4; Age at diagnosis: 49.4 years (18,039 days).
Specimen C3L-08152-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 392b89ce-f354-4d8f-a551-1be727f8b693.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08152-31 (Blood Derived Normal), aliquot CPT0511400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a50fd83-b8ea-45d5-921b-9fe560733542

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1248679583, COSV57868296; called by muse, mutect2
- ARID1A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 23/554 reads (4%) | catalogued as COSV100251003; called by muse, mutect2
- FAM181B | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 16/431 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1207858680; called by muse, mutect2
- MDGA2 | c.2651T>C p.L884P (on ENST00000399232 / NM_001113498.2; = p.L586P on NM_182830.4) | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093235, COSV62118191; called by muse, mutect2
- NLGN4X | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1051301935, COSV99321667; called by muse, mutect2
- NPR2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 21/596 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs1263762640; called by muse, mutect2
- OR52R1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs903426846, COSV61888520; called by muse, mutect2
- PCMTD2 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 36/686 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs757926855, COSV55059790; called by muse, mutect2
- PTGER3 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 39/586 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs368986881; called by muse, mutect2
- TTN | c.10435G>A p.E3479K (on ENST00000591111; = p.E3433K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/240 reads (9%) | catalogued as COSV100630993; called by muse, mutect2
- UNCX | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 35/644 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60332945; called by muse, mutect2
- CDH7 | c.2119T>G p.F707V | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP152 | c.4293A>G p.I1431M (on ENST00000380950 / NM_001194998.2; = p.I1375M on NM_014985.4) | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.246); called by muse, mutect2
- CTNND2 | c.94A>G p.S32G | Missense Mutation (SNP) | VAF 15/423 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2
- CYP26A1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2
- PLK1 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCN3A | c.1931T>C p.M644T | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.62); called by muse, mutect2
- SEZ6L2 | c.2668G>A p.E890K (on ENST00000308713 / NM_001114099.3; = p.E833K on NM_012410.4) | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SPEG | c.4823G>A p.G1608D | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CHST7 | c.432C>T p.G144= | Silent (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- GRID2IP | c.2487C>T p.S829= | Silent (SNP) | VAF 29/607 reads (5%) | catalogued as rs1210468513; called by muse, mutect2
- NMUR1 | c.942C>T p.H314= | Silent (SNP) | VAF 18/536 reads (3%) | catalogued as rs918313683, COSV59403590, COSV59404176; called by muse, mutect2
- OR6C65 | c.465T>C p.F155= | Silent (SNP) | VAF 26/389 reads (7%) | catalogued as rs371380701, COSV65568240, COSV65568769; called by muse, mutect2
- PCDHGA9 | c.429C>T p.N143= | Silent (SNP) | VAF 13/421 reads (3%) | catalogued as rs1022563452, COSV53899236; called by muse, mutect2
- TTYH3 | c.1083C>T p.T361= | Silent (SNP) | VAF 32/578 reads (6%) | catalogued as rs780884125; called by muse, mutect2
- WNK2 | c.1704G>A p.P568= | Silent (SNP) | VAF 35/759 reads (5%) | catalogued as rs542305553; called by muse, mutect2
- ZIC5 | c.1305C>T p.F435= | Silent (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
